Gene-level copy-number profile of tumor specimen TCGA-DX-A2J4-01A from TCGA case TCGA-DX-A2J4, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 60.6 years (22,131 days).
Specimen TCGA-DX-A2J4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.c5b15050-291f-4f2c-93da-1c5b2a206533.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A2J4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64b4eeda-4615-4bff-b273-3da6c3f6d783

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,387; copy number 2: 56,802; copy number 3: 39; copy number 4: 85; copy number 5: 198; copy number 6: 79; copy number 7: 20; copy number 8: 32; copy number 9: 6; copy number 10: 17; copy number 12: 8; copy number 13: 12; copy number 14: 34; copy number 15: 29; copy number 17: 2; copy number 18: 1; copy number 19: 21; copy number 20: 9; copy number 22: 21; copy number 23: 6; copy number 27: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A2J4-01A-32D-A21P-01): tumor purity 0.35, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 504 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:46,764,761–46,832,408, 1 gene, copy number 5: SLC38A4.
- chr12:47,484,689–48,442,947, 53 genes, copy number 6–14: AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1, PFKM, MIR6505, ASB8, AC074029.3, AC074029.2, PHBP18, AC074029.1, CCDC184, AC074029.4, AC024257.3, OR10AD1, AC024257.1, AC024257.5, H1-7, AC024257.2, ZNF641, AC090115.1, OR5BK1P, AC024257.4, OR5BT1P, OR5BJ1P, OR8S21P, OR8T1P.
- chr12:52,205,392–52,736,142, 38 genes, copy number 5–22 (within-gene range 2–22): LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2.
- chr12:57,591,174–57,896,482, 29 genes, copy number 15 (within-gene range 2–15): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1.
- chr12:58,244,378–58,244,865, 1 gene, copy number 13: RPL21P103.
- chr12:61,231,159–62,279,150, 7 genes, copy number 12–14 (within-gene range 2–14): AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:62,545,582–62,545,679, 1 gene, copy number 10: RNU6-399P.
- chr12:63,760,358–64,162,217, 8 genes, copy number 10–13 (within-gene range 2–13): AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1.
- chr12:64,038,562–64,397,065, 12 genes, copy number 10 (within-gene range 2–10): AC020611.2, AC025576.3, AC025576.2, AC025576.1, C12orf66, RNU6-1009P, AC012158.1, RNU5A-7P, C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1.
- chr12:64,820,179–64,868,699, 2 genes, copy number 6: AC025262.3, RPL7P39.
- chr12:65,758,020–65,966,291, 4 genes, copy number 13 (within-gene range 2–13): RPSAP52, HMGA2, AC107308.1, HMGA2-AS1.
- chr12:66,292,683–67,096,410, 7 genes, copy number 5–9 (within-gene range 2–9): RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2.
- chr12:67,424,272–67,978,387, 10 genes, copy number 7: NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1.
- chr12:68,001,394–68,001,548, 1 gene, copy number 7: RPL39P28.
- chr12:68,746,125–70,920,738, 45 genes, copy number 8–19 (within-gene range 2–19): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:75,020,969–75,209,839, 2 genes, copy number 5 (within-gene range 2–5): AC073525.1, KCNC2.
- chr12:78,326,680–79,452,008, 8 genes, copy number 14–23 (within-gene range 2–23): LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1.
- chr12:79,934,901–80,068,757, 4 genes, copy number 12–23: PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P.
- chr12:80,343,515–80,680,273, 4 genes, copy number 20: RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1.
- chr12:81,257,975–81,759,553, 1 gene, copy number 10 (within-gene range 2–10): PPFIA2.
- chr12:81,378,042–81,869,046, 3 genes, copy number 6–10: AC069228.1, AC079363.1, AC091515.1.
- chr12:84,154,434–84,294,562, 1 gene, copy number 17 (within-gene range 2–17): AC090679.2.
- chr12:84,448,625–84,449,878, 1 gene, copy number 17: AC087888.1.
- chr12:88,430,442–89,418,559, 14 genes, copy number 20–27 (within-gene range 2–27): Y_RNA, KITLG, AC024941.2, RNU1-117P, AC024941.1, LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1.
- chr12:95,791,733–100,628,288, 88 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:97,215,812–97,432,094, 2 genes, copy number 7 (within-gene range 2–7): LINC02253, AC020704.1.
- chr18:5,721,812–6,108,382, 5 genes, copy number 7: MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3.
- chr18:5,956,101–6,017,839, 2 genes, copy number 7: AP001021.2, RNU5F-3P.
- chr18:6,941,742–7,117,797, 1 gene, copy number 6 (within-gene range 2–6): LAMA1.
- chr18:7,076,817–7,232,047, 3 genes, copy number 6: AP005062.1, SLC25A51P2, LRRC30.
- chr18:14,337,423–15,330,282, 39 genes, copy number 5: CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:4,969,113–5,720,572, 14 genes, copy number 6 (within-gene range 4–6): KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4, TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1.
- chr19:7,728,958–7,769,605, 5 genes, copy number 6 (within-gene range 2–6): CLEC4G, AC008763.4, CD209, RPL21P129, CLEC4M.
- chr19:9,323,772–9,435,571, 6 genes, copy number 6: ZNF559, ZNF559-ZNF177, AC011451.2, ZNF177, AC011451.3, ZNF266.
- chr19:9,683,294–10,503,558, 53 genes, copy number 5 (within-gene range 2–5): RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1.
- chr19:12,284,337–12,365,905, 3 genes, copy number 6: AC012618.2, ZNF563, ZNF442.
- chr19:35,224,800–35,267,964, 4 genes, copy number 6 (within-gene range 2–6): FAM187B, FAM187B2P, LSR, AC002128.2.
- chr19:41,219,223–41,261,766, 2 genes, copy number 9: AXL, AC011510.1.
- chr19:41,397,808–41,425,002, 1 gene, copy number 8 (within-gene range 2–8): BCKDHA.
- chr19:41,425,359–41,652,963, 19 genes, copy number 8: AC011462.2, B3GNT8, DMAC2, Metazoa_SRP, ERICH4, PCAT19, AC243960.2, PLEKHA3P1, AC243960.3, LINC01480, AC243960.1, CEACAM21, AC243960.10, CEACAMP3, DNAJC19P2, CEACAM4, DNAJC19P3, AC243960.5, AC243960.4.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
